Somatic mutation profile of tumor specimen TCGA-DW-7841-01A (aliquot TCGA-DW-7841-01A-11D-2136-08) from TCGA case TCGA-DW-7841, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.3 years (22,403 days).
Specimen TCGA-DW-7841-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a03ff0f-c31c-43bd-a70c-876ec06cb33f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7841-10A (Blood Derived Normal), aliquot TCGA-DW-7841-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6870ec4-fc66-450f-976f-40e03e2e26a7

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2A | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51645208; called by muse, mutect2, varscan2
- BSPRY | c.1171T>A p.F391I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53058369; called by muse, mutect2, varscan2
- CTCFL | c.1113G>C p.Q371H | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV54780201; called by muse, mutect2, varscan2
- DDX52 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs954607976; called by muse, mutect2, varscan2
- FAM91A1 | c.189C>A p.Y63* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV58240356; called by muse, mutect2, varscan2
- FANCM | c.4354G>A p.A1452T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as COSV57508007; called by muse, mutect2, varscan2
- GTF3C1 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62242517, COSV62245739; called by muse, mutect2, varscan2
- HNRNPM | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs199749036, COSV55317738; called by muse, mutect2, varscan2
- KCNH5 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV59756671, COSV59781638; called by muse, mutect2, varscan2
- KPNA4 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV62075331; called by muse, mutect2, varscan2
- KRT27 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56971557, COSV56973827; called by muse, mutect2, varscan2
- LAMB3 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as rs144249951, COSV61917846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCAT | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772845218, COSV51793983; called by muse, mutect2, varscan2
- MICAL3 | c.5461G>A p.E1821K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV71588954; called by muse, mutect2, varscan2
- PCDHGA6 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 34/95 reads (36%) | catalogued as rs763545631, COSV53907715; called by muse, mutect2, varscan2
- POLDIP3 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52810533; called by muse, mutect2, varscan2
- RYR3 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1291166318, COSV66811373; called by muse, mutect2, varscan2
- SBF2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV56314165; called by muse, varscan2
- SCN7A | c.2789T>A p.I930N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV69275468; called by muse, mutect2, varscan2
- SEC14L2 | c.580+2dup p.X194_splice | Splice Site (INS) | VAF 27/118 reads (23%) | catalogued as rs1182245324; called by mutect2, pindel, varscan2
- SLC30A9 | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.283); catalogued as COSV52553956; called by muse, mutect2, varscan2
- SLCO2B1 | c.748C>A p.R250S | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as COSV56940444; called by muse, mutect2, varscan2
- SOX15 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51468251, COSV51469835; called by muse, mutect2, varscan2
- SYDE2 | c.1537A>G p.N513D | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV52318616; called by muse, mutect2
- TBPL2 | c.986T>G p.I329S | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs764308345, COSV55974085; called by muse, mutect2, varscan2
- TDRD3 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52165484; called by muse, mutect2, varscan2
- TMEM88 | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1415850814, COSV54688261; called by muse, mutect2, varscan2
- TNFAIP3 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV52803247; called by muse, mutect2, varscan2
- ZNF497 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV54053830; called by muse, mutect2, varscan2
- ACVR2A | c.1530_1534del p.S512Mfs*21 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- ADAM9 | c.781_782dup p.L262Dfs*10 | Frame Shift Ins (INS) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- COL17A1 | c.4074del p.N1359Mfs*20 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel*, varscan2
- ERRFI1 | c.196_202+11del p.X66_splice | Splice Site (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- FAAP100 | c.1809_1819del p.F603Lfs*14 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | called by mutect2, pindel, varscan2
- PDE9A | c.1318dup p.E440Gfs*4 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- PIPOX | c.399_410del p.L134_G137del | In Frame Del (DEL) | VAF 36/137 reads (26%) | called by mutect2, pindel, varscan2
- SLC35A5 | c.33_41del p.I11_L14delinsM | In Frame Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- SUSD1 | c.1929del p.F643Lfs*29 | Frame Shift Del (DEL) | VAF 31/164 reads (19%) | called by pindel, varscan2*
- KBTBD7 | c.441C>T p.A147= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV65267316; called by muse, mutect2, varscan2
- LRPPRC | c.387T>C p.S129= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53244328; called by muse, mutect2, varscan2
- MEI1 | c.2055A>C p.G685= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55908972; called by muse, mutect2, varscan2
- OXLD1 | c.144G>A p.A48= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs377125959, COSV61304127; called by muse, mutect2, varscan2
- PELP1 | c.3204G>A p.E1068= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV52593302; called by muse, mutect2, varscan2
- PWWP2A | c.738C>T p.V246= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV61048377; called by muse, mutect2, varscan2
- RPL10A | c.21C>T p.R7= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs762216520, COSV57691308; called by muse, mutect2
- TLCD1 | c.165C>A p.S55= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV52049427; called by muse, mutect2, varscan2
- ZCCHC9 | c.9G>A p.R3= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV54175943, COSV54177590; called by muse, mutect2, varscan2
